CCDI case PBBXDF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/589339fb-4a34-458b-9237-2b78dd1a4ea8

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,643 days).

Biospecimens (2 samples)
- Sample 0DKDBT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKDDI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
